Somatic mutation profile of tumor specimen TCGA-HV-A5A3-01A (aliquot TCGA-HV-A5A3-01A-11D-A26I-08) from TCGA case TCGA-HV-A5A3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 50.6 years (18,475 days).
Specimen TCGA-HV-A5A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16453ab1-c879-4b5a-a37b-6e6bffa4878d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A5A3-10A (Blood Derived Normal), aliquot TCGA-HV-A5A3-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/115106f2-13e1-4f62-b49e-2a359e960a20

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/114 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 79/230 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100986650; called by muse, mutect2, varscan2
- ADAMTS12 | c.3018C>G p.N1006K | Missense Mutation (SNP) | VAF 126/1057 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100711677; called by muse, mutect2, varscan2
- ALDH1L1 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV99857513; called by muse, mutect2, varscan2
- ATP5MC3 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV99507249; called by muse, mutect2, varscan2
- CDH8 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs375557193; called by muse, mutect2, varscan2
- COX4I2 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200392726; called by muse, mutect2, varscan2
- CPB1 | c.918C>A p.Y306* | Nonsense Mutation (SNP) | VAF 222/601 reads (37%) | catalogued as COSV51576466, COSV99294528; called by muse, mutect2, varscan2
- CPO | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 168/875 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99786660; called by muse, mutect2, varscan2
- CYP11A1 | c.698T>C p.F233S | Missense Mutation (SNP) | VAF 181/440 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99166188; called by muse, mutect2, varscan2
- ENOX1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 109/357 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99817157; called by muse, mutect2, varscan2
- EPB41L3 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 421/1414 reads (30%) | catalogued as rs781377051, CM1213159, COSV59463637; called by muse, mutect2, varscan2
- FAM180A | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs554135792, COSV100647249; called by muse, mutect2, varscan2
- FAT2 | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs142737825; called by muse, mutect2, varscan2
- FLRT2 | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 140/534 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100421017; called by muse, mutect2, varscan2
- IGF2BP2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 129/585 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs759323959, COSV60485073; called by muse, mutect2, varscan2
- MAST4 | c.7689G>T p.K2563N (on ENST00000403625 / NM_001164664.2; = p.K2374N on NM_015183.3) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV99845819; called by muse, mutect2
- MAST4 | c.7690G>T p.D2564Y (on ENST00000403625 / NM_001164664.2; = p.D2375Y on NM_015183.3) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV99845823; called by muse, mutect2
- NEK9 | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.519); catalogued as COSV99464522; called by muse, mutect2, varscan2
- PCDH15 | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1169366656, COSV100227539, COSV57401935; called by muse, mutect2, varscan2
- PDAP1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 159/535 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs761478261, COSV99403107; called by muse, mutect2, varscan2
- PSME4 | c.2804A>G p.H935R | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs183190432, COSV101122649; called by muse, varscan2
- SHANK1 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 189/404 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs757198942, COSV99522044; called by muse, mutect2, varscan2
- SMAD4 | c.1329T>A p.C443* | Nonsense Mutation (SNP) | VAF 74/192 reads (39%) | catalogued as COSV61694385; called by muse, mutect2, varscan2
- SPECC1L | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 145/470 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs200866362, COSV58657145; called by muse, mutect2, varscan2
- WNT7B | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs956976713, COSV100254783; called by muse, mutect2, varscan2
- ZNF676 | c.1621G>T p.E541* (on ENST00000650058; = p.E509* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 84/358 reads (23%) | catalogued as COSV68093232, COSV68093730; called by muse, mutect2, varscan2
- MUC2 | c.362A>T p.H121L | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TDRP | c.383del p.G128Vfs*40 | Frame Shift Del (DEL) | VAF 60/164 reads (37%) | called by mutect2, varscan2
- IFNL2 | c.306G>A p.L102= | Silent (SNP) | VAF 217/467 reads (46%) | catalogued as COSV59593434; called by muse, mutect2, varscan2
- NLRP12 | c.24C>T p.D8= | Silent (SNP) | VAF 92/464 reads (20%) | catalogued as rs577507616, COSV60745112, COSV60748820; called by muse, mutect2, varscan2
- OR2A5 | c.360C>T p.Y120= | Silent (SNP) | VAF 315/972 reads (32%) | catalogued as rs769204145, COSV101278852; called by muse, mutect2, varscan2
- OR2M3 | c.132C>T p.V44= | Silent (SNP) | VAF 402/2306 reads (17%) | catalogued as COSV101513518, COSV71759220, COSV71759349; called by muse, mutect2, varscan2
- PTPRH | c.1410C>T p.S470= | Silent (SNP) | VAF 73/367 reads (20%) | catalogued as rs1245729782, COSV54744483; called by muse, mutect2, varscan2
- ST8SIA6 | c.858G>A p.T286= | Silent (SNP) | VAF 192/1497 reads (13%) | catalogued as rs748390143, COSV101112158, COSV66471233; called by muse, mutect2, varscan2
- UBR4 | c.7423C>T p.L2475= | Silent (SNP) | VAF 185/1170 reads (16%) | catalogued as COSV100921857; called by muse, mutect2, varscan2
- ZNF629 | c.2577C>T p.L859= | Silent (SNP) | VAF 99/303 reads (33%) | catalogued as rs1438768386, COSV52699876; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726171 T>G | 3'Flank (SNP) | VAF 66/183 reads (36%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-9540G>T | Intron (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99246819; called by muse, varscan2
